Somatic mutation profile of tumor specimen BA3027D (aliquot aq-BA3027D) from BEATAML1.0 case 2324, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Therapy related myeloid neoplasm; Tissue or organ of origin: Bone marrow; Age at diagnosis: 53.6 years (19,571 days).
Specimen BA3027D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ff528496-cc33-48a5-a9c4-82aa640b3b52.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2680D (Solid Tissue Normal), aliquot aq-BA2680D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/065c1cc7-e223-46ec-b14a-391651b97fb4

The open-access MAF lists 6 somatic variants for this specimen: 6 protein-altering or splice-affecting.
By variant classification: Missense Mutation 6.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IFI44L | c.1146C>A p.S382R | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs1298967683; called by muse, mutect2
- ABCA2 | c.6465G>T p.Q2155H (on ENST00000614293; = p.Q2125H on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.035); called by muse, mutect2
- ABTB2 | c.838G>T p.V280F | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); called by muse, mutect2
- CARD10 | c.640G>T p.A214S | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- CNTLN | c.875C>A p.A292E | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.865); called by muse, mutect2
- NALCN | c.4608G>T p.M1536I | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.135); called by muse, mutect2
